Gene-level copy-number profile of tumor specimen TCGA-05-4410-01A from TCGA case TCGA-05-4410, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.7 years (22,888 days).
Specimen TCGA-05-4410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fd3c6b7e-443d-4b30-a9b7-fd9e306cc833.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4410-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bb19837a-16c8-43b6-9087-5460deec9f4a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 451; copy number 1: 3,688; copy number 2: 13,159; copy number 3: 24,234; copy number 4: 9,510; copy number 5: 6,384; copy number 6: 2,141; copy number 7: 163; copy number 8: 16; copy number 9: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4410-01A-21D-1854-01): tumor purity 0.24, ploidy 4.49, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 451 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–19,277,573, 451 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 243 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:38,276,178–40,630,875, 64 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr5:58,198–8,366,437, 163 genes, copy number 7 (broad region; genes not listed).
- chr5:20,611,806–22,853,344, 16 genes, copy number 8 (within-gene range 6–8): LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2.

Autosomal genes at a single copy (total copy number 1): 2,030. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
